Surgical pathology report (de-identified scan), TCGA case TCGA-DV-5568, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DV-5568-01A (Primary Tumor).

[page 1 of 4]
DIAGNOSIS:

- 1. Kidney, right, "tumor #1" (excision): Cyst with fibrosis.
- 2. Kidney, right, "tumor #2" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.
- 3. Kidney, right, "tumor #3" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.
- 4. Kidney, right, "tumor #4" (excision): Fibrous tissue.
- 5. Kidney, right, "tumor #5" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.
- 6. Kidney, right, "tumor #6" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.
- 7. Kidney, right, "tumor #7" (excision): Renal cyst lined by atypical cells.
- 8. Kidney, right, "tumor #8" (excision): Renal cyst lined by atypical cells.
- 9. Kidney, right, "tumor #9" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.
- 10. Kidney, right, "tumor #10" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.
- 11. Kidney, right, "tumor #11" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.
- 12. Kidney, right, "tumor #12" (excision): Fibrous tissue and renal parenchyma.
- 13. Kidney, right, "tumor #13" (excision): Renal cell carcinoma, clear cell type, Furhman nuclear grade II.

NOTE:

Patient Identification

[page 2 of 4]
CLINICAL INFORMATION: Brief Clinical History: history of VHL, bilateral renal massess
Specimen Taken For Protocol: ☒ Yes Allocate Order to Protocol:

PROCEDURE:

SPECIMENS SUBMITTED: 1. KIDNEY, RIGHT, Tumor
2. KIDNEY, RIGHT, Tumor
3. KIDNEY, RIGHT, Tumor
4. KIDNEY, RIGHT, Tumor
5. KIDNEY, RIGHT, Tumor
6. KIDNEY, RIGHT, Tumor
7. KIDNEY, RIGHT, Tumor
8. KIDNEY, RIGHT, Tumor
9. KIDNEY, RIGHT, Tumor
10. KIDNEY, RIGHT, Tumor
11. KIDNEY, RIGHT, Tumor
12. KIDNEY, RIGHT, Tumor
13. KIDNEY, RIGHT, Tumor

GROSS DESCRIPTION: Received are 13 containers labeled with the patient's name, medical record number, and further specified as:

1. "Tumor #1 right kidney". The specimen consists of a cystic soft tissue mass that has been opened to reveal a smooth cavity that appears loculated. The specimen measures 1.5 x 1.2 x 1.0 cm. The specimen is serially sectioned and representative sections are submitted in white cassette labeled for permanent processing.
2. "Tumor #2 right kidney". The specimen consists of a red-tan soft tissue mass measuring 1.3 x 1.0 x 1.0 cm. 75% of the tumor is procured for the UOB Lab. The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The cut surface of the tumor reveals a yellow solid tumor mass. The specimen is sectioned and entirely submitted in white cassette labeled for permanent processing.
3. "Tumor #3 right kidney". The specimen consists of a 0.8 x 0.5 x 0.2 cm soft tissue mass. 50% of the tumor is procured by the . The remaining tissue is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The specimen is entirely submitted in white cassette labeled for permanent processing.

Patient Identification

[page 3 of 4]
4. "Tumor #4 right kidney". The specimen consists of a red-tan soft tissue mass measuring 0.5 x 0.5 x 0.3 cm. The specimen is entirely submitted in white cassette labeled [REDACTED] for permanent processing.
5. "Tumor #5 right kidney". The specimen consists of a red-tan soft tissue mass measuring 1.5 x 1.5 x 1.2 cm. Approximately 60% of the tumor is procured for the [REDACTED]. The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The cut surface of the tumor reveals a yellow solid tumor nodule. The specimen is serially sectioned and entirely submitted in white cassette labeled [REDACTED] for permanent processing.
6. "Tumor #6 right kidney". The specimen consists of a red-tan soft tissue mass measuring 0.8 x 0.8 x 0.5 cm. Approximately 50% of the specimen is procured by the [REDACTED]. The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The specimen is entirely submitted in white cassette labeled [REDACTED] for permanent processing.
7. "Tumor #7 right kidney". The specimen consists of a red-tan soft tissue mass measuring 1.0 x 1.0 x 0.5 cm. The specimen is entirely submitted in white cassette labeled [REDACTED] for permanent processing.
8. "Tumor #8 right kidney". The specimen consists of a red-tan soft tissue fragment measuring 0.6 x 0.2 x 0.2 cm. The specimen is entirely submitted in white cassette labeled [REDACTED] for permanent processing.
9. "Tumor #9 right kidney". The specimen consists of a 1.0 x 0.8 x 0.6 cm soft tissue fragment. Approximately 60% is procured for the [REDACTED]. The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The specimen is entirely submitted in white cassette labeled [REDACTED] for permanent processing.
10. "Tumor #10 right kidney". The specimen consists of a red-tan soft tissue mass measuring 3 x 3 x 3 cm. Approximately 75% is procured by the [REDACTED]. The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The cut surface of the tumor reveals a yellow necrotic cut surface. The specimen is serially sectioned and representative section is submitted in white cassette labeled [REDACTED] for permanent processing.
11. "Tumor #11 right kidney". The specimen consists of a red-tan soft tissue mass measuring 1 x 1 x 1 cm. Approximately 50% of the tumor is procured by the [REDACTED]. The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The specimen is serially sectioned to reveal a yellow-red cut surface. The specimen is entirely submitted in white cassette labeled [REDACTED] for permanent processing.

Patient Identification

[page 4 of 4]
12. "Tumor #12 right kidney". The specimen consists of a red-tan soft tissue mass measuring 0.6 x 0.5 x 0.4 cm. Approximately 50% of the tumor is procured by the [REDACTED]. The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The specimen is entirely submitted in white cassette labeled [REDACTED] for permanent processing.
13. "Tumor #13 right kidney". The specimen consists of a red-tan soft tissue mass measuring 1.7 x 1.2 x 1.2 cm. Approximately 50% of the tumor is procured for the [REDACTED]. The remaining specimen is sent to Surgical Pathology. In Surgical Pathology, the specimen received matches the above description. The specimen is serially sectioned to reveal a yellow-red cut surface. Representative sections are submitted in white cassette labeled [REDACTED] for permanent processing.

[REDACTED]

No consultants

Patient Identification

Source: NCI Genomic Data Commons file ec46c3c6-d9ca-4d8c-b648-0a7e5b7f2955 (TCGA-DV-5568.6102167A-DC99-4515-BB5C-E545B592C309.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).